Somatic mutation profile of tumor specimen TCGA-OR-A5K8-01A (aliquot TCGA-OR-A5K8-01A-11D-A29I-10) from TCGA case TCGA-OR-A5K8, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 39.5 years (14,435 days).
Specimen TCGA-OR-A5K8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b71f68e9-626f-4e01-9cbc-4bc07a87a683.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5K8-10A (Blood Derived Normal), aliquot TCGA-OR-A5K8-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0c8eec8-2258-4502-b4ee-3c6b27c14b39

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 16, Silent 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK19 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60449076; called by mutect2, varscan2
- CUX1 | c.869T>C p.V290A (on ENST00000292535 / NM_181552.4; = p.V301A on NM_001913.5) | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782723864; called by muse, mutect2, varscan2
- LRRN1 | c.1250A>T p.D417V | Missense Mutation (SNP) | VAF 78/94 reads (83%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as COSV60014108; called by muse, varscan2
- MINK1 | c.3008G>A p.R1003Q | Missense Mutation (SNP) | VAF 72/86 reads (84%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as rs370042103; called by muse, mutect2, varscan2
- SMARCA2 | c.2149G>T p.A717S | Missense Mutation (SNP) | VAF 91/226 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61810717; called by muse, mutect2, varscan2
- ATF7IP | c.2120A>C p.E707A | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- ATP10B | c.1672G>T p.A558S | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- BCAR1 | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 83/179 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- CDR1 | c.766A>G p.T256A | Missense Mutation (SNP) | VAF 139/145 reads (96%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- CMYA5 | c.4813G>C p.D1605H | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DAXX | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 63/77 reads (82%) | called by muse, mutect2, varscan2
- GTF2I | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, varscan2
- HHIPL2 | c.177G>T p.E59D | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC16 | c.26990C>A p.T8997K | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- PGS1 | c.425A>G p.E142G | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- RP1 | c.3914T>C p.L1305P | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC44A2 | c.956-14_981del p.X319_splice | Splice Site (DEL) | VAF 22/76 reads (29%) | called by mutect2, pindel
- TTC7A | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.254); called by muse, mutect2
- CRHR1 | c.741G>A p.V247= (on ENST00000398285 / NM_001145146.2; = p.V218= on NM_004382.5) | Silent (SNP) | VAF 67/76 reads (88%) | catalogued as rs369145044; called by muse, mutect2, varscan2
- LAMA4 | c.3423C>A p.I1141= (on ENST00000230538 / NM_001105206.3; = p.I1134= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/25 reads (80%) | called by muse, mutect2, varscan2
